Surgical pathology report (de-identified scan), TCGA case TCGA-KO-8417, project TCGA-KICH (Kidney Chromophobe), tissue source site MD Anderson Cancer Center, specimen TCGA-KO-8417-01A (Primary Tumor).

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (5.0 CM IN MAXIMUM DIMENSION), CHROMOPHOBE TYPE, FUHRMAN NUCLEAR GRADE 3, CONFINED TO THE KIDNEY.

Margins of resection (ureter, renal vein and artery and perinephric adipose tissue), no tumor present.

(B) GALLBLADDER:

Chronic cholecystitis and cholelithiasis.

No tumor present.

COMMENT

The tumor is composed of polygonal cells with prominent cell membranes and thick-walled blood vessels. There are focal areas showing prominent tubular and papillary features. On immunostains, the tumor is positive for CK7 and c-kit, partially positive for AMACR, and negative for vimentin and CD 10. Based on these morphologic and immunohistochemical features, this tumor is consistent with chromophobe renal cell carcinoma.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A nephrectomy specimen (16.0 x 10.0 x 7.0 cm) composed of kidney (11.0 x 7.0 x 7.0 cm), renal vein, renal artery and ureter (7.5 cm in length and 0.5 cm on average diameter). A well-circumscribed fleshy tan tumor (5.0 x 4.5 x 2.0 cm) is identified in the lower pole involving the cortex and medulla. The tumor is confined to the kidney capsule. Sectioning through the tumor revealed a homogeneous fleshy tan-brown tumor with no hemorrhage or necrosis. The tumor is not extending to the perinephric fat or the renal sinuses. The tumor is not involving the renal vein. No adrenal gland is identified. The ureter is unremarkable.

A piece is taken for electron microscopic examination and tissue bank.

INK CODE: Black - Gerota's fascia.

SECTION CODE: A1, ureter and vascular margins shave and submitted en face; A2, A3, renal sinus; A4, tumor with pelvis; A5, A6, tumor with inked Gerota's fascia; A7, tumor with capsule; A8-A11, tumor with surrounding kidney; A12, A13, representative section of the tumor; A14, A15, normal kidney. [REDACTED]

(B) GALLBLADDER - A gallbladder (9.0 x 3.0 x 4.0 cm).

The cystic duct is probe patent (0.4 cm in length and 0.3 cm in average diameter). The serosal surface of the gallbladder is tan-pink and smooth. The wall thickness ranges between 0.2 to 0.3 cm. The mucosa is covered with thick bile. Nineteen stones are identified, ranging between 0.7 to 1.2 cm in largest dimension. The stones are brown-green and have a regular shape.

SECTION CODE: B1, cystic duct; B2, B3, representative section of the gallbladder wall. [REDACTED]

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

[REDACTED]

Source: NCI Genomic Data Commons file cf20adec-956c-4b28-ae95-4ec6c5f90e5a (TCGA-KO-8417.6CD3D366-B7CC-4E94-874E-A8EA2BA07701.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).